CPTAC case C3L-00459 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/80b433c2-530a-4589-8ddc-0124a61240d3

Demographics
Sex at birth: male; Race: white; Year of birth: 1941; Vital status: Dead; Days to death: 39 days; Year of death: 2017; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.7 years (27,646 days); Year of diagnosis: 2016; Days to last known disease status: 39 days; Progression or recurrence: no; Days to last follow up: 39 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 39.

Other clinical attributes
- Weight: 83 kg; Height: 175 cm; BMI: 27.1; Comorbidities: Hypertension.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (6 samples)
- Sample C3L-00459-34: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC). An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample C3L-00459-51: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Samples C3L-00459-52, C3L-00459-53 (2 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-00459-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 4 days; Time between excision and freezing: 280 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample C3L-00459-58: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 4 days; Time between excision and freezing: 280 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
